Gene-level copy-number profile of tumor specimen TCGA-BB-4228-01A from TCGA case TCGA-BB-4228, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Base of tongue, NOS; AJCC pathologic stage: Stage III; Tumor grade: GX; Age at diagnosis: 50.7 years (18,536 days).
Specimen TCGA-BB-4228-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.58b753fa-9bf9-4450-a2bc-abab010790b8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BB-4228-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/be7bcee2-bc7b-4edb-8b53-a3082cf6aac2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 7,158; copy number 2: 47,768; copy number 3: 2,197; copy number 4: 82; copy number 5: 2,458; copy number 6: 156.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BB-4228-01A-01D-1432-01): tumor purity 0.9, ploidy 2.08, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,614 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–33,298,066, 504 genes, copy number 5 (broad region; genes not listed).
- chr8:23,084,355–145,066,685, 1,954 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr20:30,278,906–32,743,567, 79 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr20:33,161,768–35,280,043, 77 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,771. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
